Somatic mutation profile of tumor specimen TCGA-CW-5587-01A (aliquot TCGA-CW-5587-01A-01D-1534-10) from TCGA case TCGA-CW-5587, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.1 years (22,693 days).
Specimen TCGA-CW-5587-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a4b08c1-8c72-44f9-b2c4-3b88b7bc1bfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-5587-11A (Solid Tissue Normal), aliquot TCGA-CW-5587-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3eb68cf0-0ce5-4005-8702-a156ff72cf6c

The open-access MAF lists 77 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 15, Frame Shift Del 7, Splice Site 3, Frame Shift Ins 3, Nonsense Mutation 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.477del p.E160Sfs*10 | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | catalogued as rs730882020, CD093920, CM961430, COSV56545604, COSV56548401; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACAP1 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99341936; called by muse, mutect2, varscan2
- ADAM2 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99697795; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV101002034; called by muse, mutect2, varscan2
- AFDN | c.2244C>A p.D748E | Missense Mutation (SNP) | VAF 78/345 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV100653461; called by muse, mutect2, varscan2
- AGRN | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101039048; called by muse, mutect2, varscan2
- ALDH3A2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.081); catalogued as rs766919052, COSV99450188, COSV99450385; called by muse, mutect2, varscan2
- ARHGEF6 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.04); catalogued as rs775679886, COSV99166671; called by muse, mutect2, varscan2
- BNIP1 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99199439; called by muse, mutect2, varscan2
- BRWD3 | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 28/575 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs768212341, COSV100956444; called by muse, mutect2
- C2CD2 | c.1926del p.D643Tfs*4 | Frame Shift Del (DEL) | VAF 28/149 reads (19%) | catalogued as rs747628044; called by mutect2, pindel, varscan2
- CNBD1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV101572886; called by muse, mutect2, varscan2
- CYB5R4 | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV100859745; called by muse, mutect2, varscan2
- DDX46 | c.1166A>T p.K389M | Missense Mutation (SNP) | VAF 165/852 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100844917; called by muse, mutect2, varscan2
- ELOB | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1302786033, COSV99241686; called by muse, mutect2
- ENDOG | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.124); catalogued as COSV100778251; called by muse, mutect2, varscan2
- F2R | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 107/626 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1561631381, COSV100058622; called by muse, mutect2, varscan2
- FBP1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1564191912; called by muse, mutect2
- FBXO43 | c.53C>G p.T18S | Missense Mutation (SNP) | VAF 108/495 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV101413910; called by muse, mutect2, varscan2
- FTSJ3 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 98/487 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.747); catalogued as rs1354124034, COSV100037428; called by muse, mutect2, varscan2
- G6PD | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV100855113; called by muse, mutect2, varscan2
- GLDC | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1356375715, COSV100394520; called by muse, mutect2, varscan2
- LAMA4 | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.253); catalogued as rs782587495, COSV100039274; called by muse, mutect2, varscan2
- MACF1 | c.4605G>T p.Q1535H | Missense Mutation (SNP) | VAF 46/240 reads (19%) | catalogued as COSV99246426; called by muse, mutect2, varscan2
- MEOX1 | c.22T>A p.C8S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100233790; called by mutect2, varscan2
- MKLN1 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 118/470 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV100759983, COSV61762460; called by muse, mutect2, varscan2
- MT1X | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV101094115; called by muse, mutect2
- MYH15 | c.3520G>A p.E1174K | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV99844143; called by muse, mutect2, varscan2
- NBEA | c.5680A>G p.K1894E | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as rs1210787988, COSV100083594; called by muse, mutect2, varscan2
- NOL7 | c.589T>G p.S197A | Missense Mutation (SNP) | VAF 111/559 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99163615; called by muse, mutect2, varscan2
- NUP62 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100352307; called by muse, mutect2, varscan2
- OR2V2 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV100080224; called by muse, mutect2, varscan2
- OR8G2P | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as rs936386399; called by muse, mutect2, varscan2
- PARN | c.823_824insT p.H275Lfs*5 | Frame Shift Ins (INS) | VAF 68/409 reads (17%) | catalogued as COSV100421343; called by mutect2, pindel, varscan2
- PIAS2 | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV100245508; called by muse, mutect2, varscan2
- PLPP1 | c.504T>A p.Y168* | Nonsense Mutation (SNP) | VAF 88/548 reads (16%) | catalogued as COSV99301993; called by muse, mutect2, varscan2
- PTTG1 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99775800; called by muse, mutect2, varscan2
- RNF19A | c.31A>G p.K11E | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as rs1482977965, COSV100348062; called by muse, mutect2, varscan2
- RUFY1 | c.1714T>G p.S572A | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100106396; called by muse, mutect2, varscan2
- SF3B6 | c.150-2A>C p.X50_splice | Splice Site (SNP) | VAF 104/316 reads (33%) | catalogued as COSV99272966; called by muse, mutect2
- SGK1 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs780432540, COSV99399028; called by muse, mutect2, varscan2
- SLCO1B3 | c.1678G>C p.V560L | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV99682141; called by muse, mutect2, varscan2
- SLIT1 | c.1013+1G>T p.X338_splice | Splice Site (SNP) | VAF 17/79 reads (22%) | catalogued as COSV99822349; called by muse, mutect2, varscan2
- ST3GAL4 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.65); catalogued as rs11559148, COSV57105749; called by muse, mutect2, varscan2
- STRBP | c.272T>A p.V91D | Missense Mutation (SNP) | VAF 148/643 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100724323; called by muse, mutect2, varscan2
- TBL1X | c.1088C>A p.A363D | Missense Mutation (SNP) | VAF 169/797 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.864); catalogued as COSV99483095; called by muse, mutect2, varscan2
- TINF2 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99945687; called by muse, mutect2, varscan2
- USO1 | c.2237A>G p.Q746R | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99363124; called by muse, mutect2
- VPS39 | c.2049T>A p.F683L (on ENST00000348544 / NM_001301138.2; = p.F672L on NM_015289.5) | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.553); catalogued as COSV100529529; called by muse, mutect2, varscan2
- ZC3H11A | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142683; called by muse, mutect2
- ZSCAN29 | c.429G>C p.R143S | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs28493274, COSV53019283, COSV99539379; called by muse, mutect2
- CENPE | c.834-2_834-1insAAA p.X278_splice | Splice Site (INS) | VAF 42/211 reads (20%) | called by mutect2, pindel, varscan2
- CHD7 | c.3142_3150delinsTGAC p.G1048* | Nonsense Mutation (DEL) | VAF 44/271 reads (16%) | called by pindel, varscan2*
- DDX18 | c.1971_1972del p.I658* | Frame Shift Del (DEL) | VAF 40/281 reads (14%) | called by pindel, varscan2
- ECI2 | c.962del p.F321Sfs*14 (on ENST00000380118 / NM_206836.3; = p.F291Sfs*14 on NM_006117.2) | Frame Shift Del (DEL) | VAF 60/387 reads (16%) | called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.2334_2341delinsA p.E780Ifs*78 | Frame Shift Del (DEL) | VAF 86/608 reads (14%) | called by pindel, varscan2*
- GOLT1A | c.165del p.W57Gfs*81 | Frame Shift Del (DEL) | VAF 31/191 reads (16%) | called by mutect2, pindel, varscan2
- ITGA9 | c.774_788del p.P259_D263del | In Frame Del (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- PDHA1 | c.622dup p.Y208Lfs*16 | Frame Shift Ins (INS) | VAF 86/405 reads (21%) | called by mutect2, pindel, varscan2
- TIAL1 | c.457_464del p.N153Cfs*21 | Frame Shift Del (DEL) | VAF 35/203 reads (17%) | called by mutect2, pindel, varscan2
- TRIP12 | c.4101dup p.I1368Yfs*4 | Frame Shift Ins (INS) | VAF 126/431 reads (29%) | called by mutect2, pindel, varscan2
- BCORL1 | c.5124T>G p.S1708= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99500704; called by muse, mutect2
- CDHR2 | c.1980C>T p.R660= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56146968; called by muse, mutect2, varscan2
- CDKN2AIP | c.1029C>G p.S343= | Silent (SNP) | VAF 40/228 reads (18%) | catalogued as COSV100187714; called by muse, mutect2
- CTR9 | c.3294T>A p.G1098= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV100797504; called by muse, mutect2, varscan2
- FCAR | c.702A>G p.A234= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV100629176; called by muse, mutect2
- FKBP15 | c.510T>G p.A170= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as COSV99439624; called by muse, mutect2
- KIF16B | c.3951G>A p.G1317= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as rs753266659, COSV100734839; called by muse, mutect2, varscan2
- MAGEB18 | c.894C>G p.A298= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV100305610, COSV57465457; called by muse, mutect2
- MVK | c.789C>G p.P263= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as rs146181903; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- OR10H1 | c.90G>C p.L30= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as COSV100612481; called by muse, mutect2, varscan2
- PCDHA13 | c.198G>A p.V66= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs782656797, COSV99169422; called by muse, mutect2, varscan2
- SESTD1 | c.30G>A p.L10= | Silent (SNP) | VAF 22/708 reads (3%) | catalogued as COSV101468171; called by muse, mutect2
- SPAM1 | c.1059C>A p.L353= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as COSV99773085, COSV99773381; called by muse, mutect2
- TAAR6 | c.435C>T p.T145= | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as rs530149491, COSV51583847; called by muse, mutect2, varscan2
- ZNF746 | c.1908G>T p.L636= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100502560; called by muse, mutect2, varscan2
- MFSD12 | chr19:3542927 A>T | 3'Flank (SNP) | VAF 22/115 reads (19%) | catalogued as COSV100281504; called by muse, mutect2, varscan2
